CCDI case PBBWBP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/f32411b6-6b9b-4a59-a467-151b3d313f27

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 12.7 years (4,641 days).

Biospecimens (3 samples)
- Sample 0DIW66: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIW72: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIW83: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
